Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7435, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7435-01A (Primary Tumor).

[page 1 of 2]
SUPPLEMENTAL REPORT

COMMENT: Squamous carcinoma involving mandibular bone.

DIAGNOSIS

- (A) RIGHT NECK DISSECTION:
METASTATIC SQUAMOUS CARCINOMA IN 2 OF 22 LYMPH NODES (0/10 LEVEL I
AND 2/12 LEVEL II).
- (B) LEFT NECK DISSECTION:
Nine lymph nodes, no tumor present.
- (C) ANTERIOR MARGIN:
Squamous mucosa, no tumor present.
- (D) TEETH:
Gross only.
- (E) TONGUE MARGIN:
Squamous mucosa, no tumor present.
- MANDIBLE, TONGUE:
INVASIVE SQUAMOUS CARCINOMA, MODERATELY DIFFERENTIATED, WITH
VASCULAR INVASION AND PERINEURAL INVASION.
Resection margins, free of tumor.
-

GROSS DESCRIPTION

(A) RIGHT NECK DISSECTION (LEVELS 1 PLUS II-CLAMP ON LEVEL II) - A fragment of fibroadipose tissue (10.0 x 3.4 x 1.0 cm), with a surgical clamp near one extremity. Adjacent to the clamp there is a gland (2.5 x 2.0 x 1.7 cm), with pale tan lobulated surface. Several lymph nodes are identified, the two largest grossly replaced by tumor and measuring up to 2.5 cm.

The lymph nodes adjacent to the gland and to one side of the clamp are submitted from section A1-A4. The opposite end of the specimen are submitted

[page 2 of 2]
[REDACTED]

in A4 to A12.

SECTION CODE: A1, three lymph nodes; A2, six lymph nodes; A3, four lymph nodes; A4, salivary gland; A5, two lymph nodes; A6, four lymph nodes; A7, one lymph node, grossly replaced by tumor; A8, three lymph nodes; A9, two lymph nodes; A10, one lymph node, grossly replaced by tumor; A11, A12, firm fibroadipose tissue, possible lymph nodes (?).

(B) LEFT NECK DISSECTION (LATERAL 1, CLAMP ON LEVEL 1) - A fragment of fibroadipose tissue (4.5 x 2.5 x 1.7 cm), with an attached surgical clamp, and a glandular structure (2.7 x 2.5 x 1.5 cm), with pale tan lobulated surface. Sectioning reveal several lymph nodes ranging from 0.2 to 0.8 cm in maximum dimension, grossly unremarkable. All the lymph nodes are submitted.

SECTION CODE: B1, gland; B2, three possible lymph nodes; B3, two possible lymph nodes; B4, one lymph node, bisected.

(C) ANTERIOR MARGIN - A strip of pale pink mucosa (5.0 x 0.2 x 0.1 cm), inked blue on one surface. The specimen is bisected and submitted in toto for frozen section C1 and C2, en face.

(D) TEETH

(E) TONGUE MARGIN, TRUE MARGIN INKED - A fragment of tan-pink soft tissue (6.6 x 1.2 x 0.4 cm). Blue, marking the true margin, is noted on one surface. In addition, the specimen is received on a telfa pad, marking the left and right aspects.

INK CODE: Red-right true margin, black-left true margin.

SECTION CODE: E1-E6, specimen serially sectioned from right to left and entirely submitted as perpendicular section for frozen section examination.

*FS/DX: SQUAMOUS MUCOSA, NO TUMOR PRESENT.

(F) MANDIBLE, TONGUE - A composite resection of floor of mouth and mandible and tongue. A tumor is noted in the floor of mouth. The mass measures 3.5 x 3.0 x 1.8 cm. The closest gross margin is the mucosal margin on the far left side of the specimen. The tumor is grossly appears not to involve the margins of resection and appears to invade the anterior aspect of the mandibular bone. The specimen is submitted sequentially from left to right under F1-F21.

SNOMED CODES

M-80703 T-51200

Source: NCI Genomic Data Commons file 052b997f-4193-433c-b863-5d4a3076a896 (TCGA-CV-7435.1332FD99-2F1D-4DF7-88B0-0FC862E6C808.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).